Somatic mutation profile of cancer-model specimen HCM-CSHL-0601-C25-85A (3D Organoid, passage 9; aliquot HCM-CSHL-0601-C25-85A-01D-A82H-36), derived from the metastatic tumor of HCMI case HCM-CSHL-0601-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 61.2 years (22,356 days).
Specimen HCM-CSHL-0601-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dca31f45-41bc-4d7c-9c17-fe971a860f33.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0601-C25-10A (Blood Derived Normal), aliquot HCM-CSHL-0601-C25-10A-01D-A82H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69fe19d8-e25d-490b-8e21-9dcf61a1be42

The open-access MAF lists 115 somatic variants for this specimen: 82 protein-altering or splice-affecting, 32 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 75, Silent 32, Nonsense Mutation 6, 3'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- COL18A1 | c.3613C>T p.R1205* (on ENST00000359759 / NM_130444.3; = p.R970* on NM_030582.4) | Nonsense Mutation (SNP) | VAF 444/446 reads (100%) | catalogued as rs1555870809; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 257/370 reads (69%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.818G>A p.R273H | Missense Mutation (SNP) | VAF 250/250 reads (100%) | hotspot (GDC flag); SIFT tolerated (0.13); PolyPhen possibly damaging (0.643); catalogued as rs28934576, CM004342, CM010472, CM920677, COSV52660980, COSV52664805, COSV52676050, COSV52728930; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ACACB | c.5281C>T p.R1761* | Nonsense Mutation (SNP) | VAF 43/335 reads (13%) | catalogued as rs568475654; called by muse, mutect2, varscan2
- ADAMTSL3 | c.2069G>A p.R690H | Missense Mutation (SNP) | VAF 243/391 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs148020587, COSV54447515; called by muse, mutect2, varscan2
- AGBL1 | c.2294C>T p.T765M | Missense Mutation (SNP) | VAF 118/326 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767364604, COSV101224391, COSV66858368; called by muse, mutect2, varscan2
- AMER3 | c.2536C>T p.Q846* | Nonsense Mutation (SNP) | VAF 40/685 reads (6%) | catalogued as rs1275027775; called by muse, mutect2
- ANKRD30A | c.1902G>T p.E634D (on ENST00000611781; = p.E578D on NM_052997.2) | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0.051); catalogued as COSV100653159; called by muse, mutect2, varscan2
- ANKRD30B | c.3419G>A p.R1140K | Missense Mutation (SNP) | VAF 41/285 reads (14%) | SIFT tolerated (0.39); PolyPhen benign (0.041); catalogued as rs762749479; called by muse, mutect2
- BPI | c.835G>A p.A279T (on ENST00000262865; = p.A275T on NM_001725.3) | Missense Mutation (SNP) | VAF 258/526 reads (49%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs142882330; called by muse, mutect2, varscan2
- CACNA1H | c.6199G>A p.V2067I | Missense Mutation (SNP) | VAF 333/1077 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs370883583; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CD1D | c.656G>A p.R219H | Missense Mutation (SNP) | VAF 200/421 reads (48%) | SIFT tolerated (0.47); PolyPhen benign (0.03); catalogued as rs199860570, COSV63809742; called by muse, mutect2, varscan2
- CDC42BPG | c.4054C>G p.P1352A | Missense Mutation (SNP) | VAF 87/393 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.285); catalogued as rs1243399507; called by muse, mutect2, varscan2
- CDC73 | c.334G>A p.A112T | Missense Mutation (SNP) | VAF 13/378 reads (3%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.979); catalogued as rs952579366, COSV66470087; ClinVar: uncertain significance; called by muse, mutect2
- CNTNAP1 | c.439C>T p.R147C | Missense Mutation (SNP) | VAF 160/699 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV52853172, COSV52853898; called by muse, mutect2, varscan2
- DAO | c.571C>T p.R191* | Nonsense Mutation (SNP) | VAF 75/432 reads (17%) | catalogued as rs760006596, COSV57324867; called by muse, mutect2, varscan2
- DIP2C | c.803C>T p.P268L | Missense Mutation (SNP) | VAF 104/329 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1305551462; called by muse, mutect2, varscan2
- FBLN1 | c.1225C>T p.R409C | Missense Mutation (SNP) | VAF 200/439 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as rs1218807619; called by muse, mutect2, varscan2
- FBXL7 | c.991G>A p.V331I | Missense Mutation (SNP) | VAF 214/638 reads (34%) | SIFT tolerated (0.29); PolyPhen benign (0.036); catalogued as rs762341690, COSV61641347; called by muse, mutect2, varscan2
- FOXB1 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 149/479 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68525748; called by muse, mutect2, varscan2
- GABRB1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 46/427 reads (11%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV54970820, COSV54993087; called by muse, mutect2
- GLB1L3 | c.1054G>A p.G352R | Missense Mutation (SNP) | VAF 118/395 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs775360870, COSV101111086, COSV66280968; called by muse, mutect2, varscan2
- GLI4 | c.727C>G p.Q243E | Missense Mutation (SNP) | VAF 230/944 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV60681790; called by mutect2, varscan2
- HAS1 | c.851G>A p.R284Q | Missense Mutation (SNP) | VAF 250/653 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs200078680, COSV55787952; called by muse, mutect2, varscan2
- KCNB1 | c.1294C>T p.R432W | Missense Mutation (SNP) | VAF 208/472 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752596402, COSV65567147, COSV65567608; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIR3DL2 | c.1138G>A p.D380N | Missense Mutation (SNP) | VAF 320/888 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.006); catalogued as rs577423968; called by muse, mutect2, varscan2
- KLF8 | c.1021C>T p.R341C | Missense Mutation (SNP) | VAF 204/419 reads (49%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1016774145, COSV100808261; called by muse, mutect2, varscan2
- KRTAP4-8 | c.84C>A p.S28R | Missense Mutation (SNP) | VAF 229/1026 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.108); catalogued as COSV61564303; called by muse, mutect2, varscan2
- LRFN3 | c.817G>A p.A273T | Missense Mutation (SNP) | VAF 427/871 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1477863802, COSV55817019, COSV99873408; called by muse, mutect2, varscan2
- LRP12 | c.2048C>T p.T683M | Missense Mutation (SNP) | VAF 85/594 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.513); catalogued as rs147788045; called by muse, mutect2, varscan2
- MYH7 | c.5500G>A p.A1834T | Missense Mutation (SNP) | VAF 191/706 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.007); catalogued as rs143362532; ClinVar: uncertain significance / benign; called by muse, mutect2, varscan2
- NKX3-2 | c.316C>T p.R106C | Missense Mutation (SNP) | VAF 243/764 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.799); catalogued as rs528913823, COSV66712024; called by muse, mutect2, varscan2
- NOS1 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 449/541 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs913433943, COSV57609864; called by muse, mutect2, varscan2
- NSUN2 | c.665A>G p.Y222C | Missense Mutation (SNP) | VAF 121/372 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1178210740; called by muse, mutect2, varscan2
- OR6F1 | c.739G>A p.V247M | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs369128749; called by muse, mutect2, varscan2
- PLA2G4E | c.488G>A p.R163Q | Missense Mutation (SNP) | VAF 159/253 reads (63%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs567649717, COSV68149047, COSV68149931; called by muse, mutect2, varscan2
- PTPRT | c.203C>A p.A68E | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.345); catalogued as rs750467022; called by muse, mutect2, varscan2
- SMAGP | c.110T>C p.I37T | Missense Mutation (SNP) | VAF 99/398 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1021802210; called by muse, mutect2, varscan2
- SMARCA4 | c.3493C>T p.L1165F | Missense Mutation (SNP) | VAF 123/641 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60788571; called by muse, mutect2, varscan2
- SMC6 | c.2446C>T p.R816* | Nonsense Mutation (SNP) | VAF 94/265 reads (35%) | catalogued as rs764711697, COSV61175873; called by muse, mutect2, varscan2
- SNW1 | c.1067G>A p.R356Q | Missense Mutation (SNP) | VAF 255/389 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.953); catalogued as COSV55053017; called by muse, mutect2, varscan2
- SPPL2B | c.757G>A p.G253R | Missense Mutation (SNP) | VAF 183/763 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as rs1214918612, COSV101194609; called by muse, mutect2, varscan2
- TECR | c.140G>A p.R47H | Missense Mutation (SNP) | VAF 179/784 reads (23%) | SIFT deleterious (0.04); PolyPhen benign (0.072); catalogued as rs1462315926, COSV99295023; called by muse, mutect2, varscan2
- TNFRSF19 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 164/478 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.133); catalogued as rs748111366, COSV50312427; called by muse, mutect2, varscan2
- TRPM1 | c.3121C>T p.R1041W | Missense Mutation (SNP) | VAF 142/471 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs184390324; called by muse, mutect2, varscan2
- ZNF571 | c.152G>A p.R51H | Missense Mutation (SNP) | VAF 70/367 reads (19%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs892328935, COSV101649405; called by muse, mutect2, varscan2
- AARS1 | c.2885G>A p.R962H | Missense Mutation (SNP) | VAF 116/367 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTSL3 | c.194C>T p.S65L | Missense Mutation (SNP) | VAF 33/207 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- ANK1 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 52/390 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.573); called by muse, varscan2
- ATP13A5 | c.2490G>T p.Q830H | Missense Mutation (SNP) | VAF 38/501 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- AUH | c.523A>G p.T175A | Missense Mutation (SNP) | VAF 174/175 reads (99%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); called by muse, mutect2, varscan2
- BUD13 | c.154G>T p.V52L | Missense Mutation (SNP) | VAF 184/311 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CEP350 | c.3007C>G p.Q1003E | Missense Mutation (SNP) | VAF 207/415 reads (50%) | SIFT tolerated (0.1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DENND4B | c.2785G>C p.E929Q | Missense Mutation (SNP) | VAF 18/524 reads (3%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2
- ELAPOR2 | c.1970G>A p.C657Y (on ENST00000450689 / NM_001142749.3; = p.C490Y on NM_152748.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 99/278 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- FBXL18 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 187/604 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- GOLGA6L9 | c.502C>A p.H168N | Missense Mutation (SNP) | VAF 102/418 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, varscan2
- INPP4B | c.2221G>T p.V741L | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.058); called by muse, mutect2
- KLK13 | c.556G>A p.D186N | Missense Mutation (SNP) | VAF 103/619 reads (17%) | SIFT tolerated (0.06); PolyPhen benign (0.179); called by muse, mutect2, varscan2
- MAST3 | c.963G>T p.Q321H | Missense Mutation (SNP) | VAF 107/445 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MBD5 | c.17A>C p.E6A | Missense Mutation (SNP) | VAF 29/359 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.199); called by muse, mutect2
- MMP1 | c.284C>T p.P95L | Missense Mutation (SNP) | VAF 144/485 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- NAGS | c.55C>A p.L19M | Missense Mutation (SNP) | VAF 164/997 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.276); called by muse, mutect2, varscan2
- NHLH2 | c.74G>A p.G25D | Missense Mutation (SNP) | VAF 224/984 reads (23%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NLRP13 | c.445G>C p.E149Q | Missense Mutation (SNP) | VAF 63/456 reads (14%) | SIFT tolerated (0.14); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OTP | c.388G>A p.D130N | Missense Mutation (SNP) | VAF 155/477 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PLCG1 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 237/558 reads (42%) | SIFT deleterious (0); PolyPhen possibly damaging (0.682); called by muse, mutect2, varscan2
- PPP1R10 | c.1853G>T p.G618V | Missense Mutation (SNP) | VAF 120/950 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRDM9 | c.1347C>A p.D449E | Missense Mutation (SNP) | VAF 96/296 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- PRRT4 | c.1949C>T p.P650L | Missense Mutation (SNP) | VAF 134/631 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- RESF1 | c.3773A>G p.D1258G | Missense Mutation (SNP) | VAF 260/377 reads (69%) | SIFT tolerated (0.07); PolyPhen benign (0.31); called by muse, mutect2, varscan2
- SIK2 | c.1885G>A p.D629N | Missense Mutation (SNP) | VAF 106/340 reads (31%) | SIFT tolerated (0.24); PolyPhen benign (0); called by muse, mutect2, varscan2
- SPOCK3 | c.172T>C p.W58R | Missense Mutation (SNP) | VAF 112/187 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TBC1D10C | c.541G>A p.G181R | Missense Mutation (SNP) | VAF 386/595 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- TFDP3 | c.391C>T p.Q131* | Nonsense Mutation (SNP) | VAF 227/457 reads (50%) | called by muse, mutect2, varscan2
- TLN1 | c.1637A>G p.Q546R | Missense Mutation (SNP) | VAF 116/216 reads (54%) | SIFT tolerated (0.21); PolyPhen benign (0.183); called by muse, mutect2, varscan2
- TTN | c.65659A>C p.K21887Q (on ENST00000591111; = p.K14463Q on NM_003319.4) | Missense Mutation (SNP) | VAF 308/613 reads (50%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- ZIC4 | c.200T>G p.L67R | Missense Mutation (SNP) | VAF 206/806 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.309); called by muse, mutect2, varscan2
- ZNF536 | c.1104A>C p.K368N | Missense Mutation (SNP) | VAF 352/693 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF541 | c.3025del p.V1009Cfs*35 | Frame Shift Del (DEL) | VAF 154/822 reads (19%) | called by mutect2, pindel, varscan2
- ZNF790 | c.82G>C p.D28H | Missense Mutation (SNP) | VAF 33/532 reads (6%) | SIFT tolerated (0.11); PolyPhen benign (0.005); called by muse, mutect2
- ZSWIM9 | c.844G>A p.A282T | Missense Mutation (SNP) | VAF 209/1038 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.174); called by muse, mutect2, varscan2
- ABI3 | c.441C>T p.D147= | Silent (SNP) | VAF 116/528 reads (22%) | catalogued as rs532540685; called by muse, mutect2, varscan2
- ADCY3 | c.1134C>T p.D378= | Silent (SNP) | VAF 112/419 reads (27%) | catalogued as rs771851785; called by muse, mutect2, varscan2
- ARMC5 | c.822T>C p.A274= | Silent (SNP) | VAF 547/1029 reads (53%) | catalogued as rs963684014; called by muse, mutect2, varscan2
- BHLHE22 | c.651C>T p.G217= | Silent (SNP) | VAF 227/886 reads (26%) | catalogued as rs955256361, COSV100418047; called by muse, varscan2
- BRINP2 | c.1173C>G p.R391= | Silent (SNP) | VAF 83/534 reads (16%) | called by muse, mutect2, varscan2
- C11orf87 | c.336C>T p.G112= | Silent (SNP) | VAF 195/568 reads (34%) | catalogued as rs773370791, COSV59357318; called by muse, mutect2, varscan2
- CCDC130 | c.1014G>A p.P338= | Silent (SNP) | VAF 227/954 reads (24%) | catalogued as rs146781419; called by muse, mutect2, varscan2
- CNNM3 | c.1323C>T p.I441= | Silent (SNP) | VAF 107/538 reads (20%) | catalogued as rs755157253, COSV59708580; called by muse, mutect2, varscan2
- COG8 | c.1674G>A p.K558= | Silent (SNP) | VAF 186/569 reads (33%) | called by muse, mutect2, varscan2
- COL17A1 | c.2667A>G p.P889= | Silent (SNP) | VAF 164/466 reads (35%) | catalogued as rs1162909024; called by muse, mutect2, varscan2
- CYP3A43 | c.462T>C p.D154= | Silent (SNP) | VAF 80/223 reads (36%) | called by muse, varscan2
- DNAJB9 | c.618C>G p.V206= | Silent (SNP) | VAF 16/322 reads (5%) | called by muse, mutect2
- EIF4E1B | c.531C>T p.A177= | Silent (SNP) | VAF 153/465 reads (33%) | catalogued as rs989034254; called by muse, mutect2, varscan2
- GOLGA6L9 | c.447C>G p.A149= | Silent (SNP) | VAF 59/270 reads (22%) | called by muse, varscan2
- LAMA4 | c.900C>T p.S300= (on ENST00000230538 / NM_001105206.3; = p.S293= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 153/154 reads (99%) | catalogued as rs1306008369; called by muse, mutect2, varscan2
- MS4A7 | c.99C>T p.N33= | Silent (SNP) | VAF 78/360 reads (22%) | catalogued as rs763227318, COSV55730961; called by muse, mutect2, varscan2
- MTMR3 | c.2982G>C p.L994= | Silent (SNP) | VAF 141/545 reads (26%) | called by muse, mutect2, varscan2
- MUC12 | c.2667G>A p.P889= (on ENST00000379442; = p.P746= on NM_001164462.1) | Silent (SNP) | VAF 191/1521 reads (13%) | catalogued as rs778671820; called by muse, mutect2, varscan2
- NELL2 | c.2259G>A p.P753= | Silent (SNP) | VAF 374/494 reads (76%) | catalogued as rs139052675, COSV61574266; called by muse, mutect2, varscan2
- NHLH2 | c.75C>A p.G25= | Silent (SNP) | VAF 224/988 reads (23%) | catalogued as rs766590445, COSV100204919; called by muse, mutect2, varscan2
- PIGO | c.1261C>T p.L421= | Silent (SNP) | VAF 180/383 reads (47%) | called by muse, mutect2, varscan2
- PTCRA | c.807A>C p.A269= | Silent (SNP) | VAF 131/285 reads (46%) | called by muse, mutect2, varscan2
- RESF1 | c.2625C>A p.I875= | Silent (SNP) | VAF 65/432 reads (15%) | called by muse, mutect2, varscan2
- RSPH10B | c.189C>T p.N63= | Silent (SNP) | VAF 293/831 reads (35%) | catalogued as rs758509545, COSV61755826; called by muse, mutect2, varscan2
- RYR2 | c.15C>T p.G5= | Silent (SNP) | VAF 69/680 reads (10%) | catalogued as COSV100854129; called by muse, mutect2
- SIGLEC1 | c.1704T>C p.T568= | Silent (SNP) | VAF 192/864 reads (22%) | catalogued as COSV52469879; called by muse, mutect2, varscan2
- SNX20 | c.477C>T p.R159= | Silent (SNP) | VAF 210/651 reads (32%) | catalogued as rs1231404239, COSV56057048; called by muse, mutect2, varscan2
- SPTAN1 | c.3315A>G p.Q1105= | Silent (SNP) | VAF 288/288 reads (100%) | catalogued as rs779226167; ClinVar: likely benign; called by muse, mutect2, varscan2
- TIAM2 | c.3582C>T p.Y1194= | Silent (SNP) | VAF 69/273 reads (25%) | catalogued as rs765786977, COSV51641710; called by muse, mutect2, varscan2
- TNFRSF8 | c.1626G>T p.G542= | Silent (SNP) | VAF 114/386 reads (30%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.4881C>G p.V1627= | Silent (SNP) | VAF 291/638 reads (46%) | called by muse, mutect2, varscan2
- ZNF83 | c.1431G>A p.A477= | Silent (SNP) | VAF 512/855 reads (60%) | catalogued as rs371525133; called by muse, mutect2, varscan2
- IGHG2 | chr14:105641885 G>A | 3'Flank (SNP) | VAF 75/260 reads (29%) | catalogued as rs1350531990; called by muse, mutect2, varscan2
